MMRF case MMRF_1850 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a2f2018e-c40c-4e4a-8542-86c07bd40841

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.7 years (20,358 days); ISS stage: I; Days to last known disease status: 998 days (2.7 years); Days to last follow up: 998 days (2.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days; Days to treatment end: 68 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 274 days; Days to treatment end: 277 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 276 days; Days to treatment end: 276 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 278 days; Days to treatment end: 278 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 515 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -40 (ECOG 0): M Protein 3.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 37.6 g/L; Immunoglobulin A 5.16 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.55 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 9.5 g/dL; Glucose 5.72 mmol/L.
- Day 51 (ECOG 1): M Protein 0.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.796 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 7.78 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.92 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 4.18 mmol/L.
- Day 150 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.721 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 6.53 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 3.04 µg/mL; Lactate Dehydrogenase 11.6 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 6 mmol/L.
- Day 249 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 5.23 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.67 mmol/L.
- Day 338 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 3.56 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 6.33 mmol/L.
- Day 453 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.635 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.453 mg/dL; Immunoglobulin G 4.67 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 1.96 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L.
- Day 533 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.046 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.01 mg/dL; Immunoglobulin G 4.67 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.23 mmol/L.
- Day 625 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 5.63 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 1.69 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 5.78 mmol/L.
- Day 723 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 6.61 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 1.88 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 93 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 6.16 mmol/L.
- Day 814 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.936 mg/dL; Immunoglobulin G 6.43 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.84 g/L; Beta 2 Microglobulin 1.37 µg/mL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 5.89 mmol/L.
- Day 905 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.956 mg/dL; Immunoglobulin G 6.8 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 2.21 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 5.67 mmol/L.
- Day 998 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 7.02 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 1.95 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 6.22 mmol/L.

Other clinical attributes
- Day -40: Weight: 105 kg; Height: 187 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1850_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -40 days.
- Sample MMRF_1850_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -40 days.
